Gene-level copy-number profile of tumor specimen ALCH-B1ZF-TTP1-A from ALCHEMIST case ALCH-B1ZF, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 54.0 years (19,727 days).
Specimen ALCH-B1ZF-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file bb38dbe2-ba79-4cd7-953a-c965228f3d59.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1ZF-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,744 have no estimate.
https://portal.gdc.cancer.gov/files/c0102067-e2cf-4d9f-bc62-056e2858fdc3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 764; copy number 1: 20,557; copy number 2: 31,597; copy number 3: 4,262; copy number 4: 1,451; copy number 5: 141; copy number 6: 2; copy number 7: 76; copy number 8: 29.

Homozygous deletions (total copy number 0; autosomes only): 27 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:68,509,441–68,670,652, 6 genes (within-gene range 0–1): UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr8:43,672,823–43,674,591, 2 genes: AC139365.2, AC139365.1.
- chr17:3,714,628–3,801,188, 4 genes (within-gene range 0–1): ITGAE, AC116914.2, HASPIN, AC116914.1.
- chr18:37,305,295–37,306,333, 1 gene (within-gene range 0–1): AC090386.2.
- chr18:79,863,668–80,247,514, 14 genes: KCNG2, AC114341.1, SLC66A2, HSBP1L1, TXNL4A, AC090360.1, RBFA, RBFADN, SLC25A6P4, ADNP2, PARD6G-AS1, PARD6G, AC139100.2, AC139100.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 248 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:207,580,631–208,854,503, 34 genes, copy number 5–8 (within-gene range 2–8): METTL21A, RPS29P9, LINC01857, RNU6-664P, PPP1R14BP2, Y_RNA, CCNYL1, AC096772.1, MIR4775, FZD5, PLEKHM3, AC083900.1, RNU6-360P, RPL9P14, RNA5SP116, RPL12P17, CRYGEP, CRYGD, CRYGC, AC093698.1, CRYGB, CRYGA, C2orf80, RPSAP27, TPT1P2, IDH1, IDH1-AS1, PIKFYVE, MYL6BP1, PTH2R, ARPC1BP1, H3P9, AC019185.1, AC019185.2.
- chr2:209,424,058–209,734,118, 1 gene, copy number 5 (within-gene range 2–5): MAP2.
- chr12:57,782,761–57,959,148, 12 genes, copy number 5 (within-gene range 2–5): TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG.
- chr16:366,969–629,272, 19 genes, copy number 7 (within-gene range 3–7): MRPL28, PGAP6, Z97634.1, NME4, DECR2, AL023881.1, RAB11FIP3, Y_RNA, AL049542.1, LINC00235, CAPN15, MIR5587, MIR3176, Z97986.1, PRR35, PIGQ, NHLRC4, Z98883.1, RAB40C.
- chr16:2,339,150–2,426,699, 1 gene, copy number 7 (within-gene range 3–7): ABCA17P.
- chr16:2,981,175–4,339,597, 73 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr16:4,331,549–4,615,027, 18 genes, copy number 5: PAM16, AC012676.1, CORO7-PAM16, AC012676.5, CORO7, VASN, DNAJA3, AC012676.3, AC012676.4, AC012676.2, NMRAL1, HMOX2, CDIP1, AC023830.3, C16orf96, AC023830.2, SUB1P3, UBALD1.
- chr16:4,882,507–4,960,741, 1 gene, copy number 6 (within-gene range 3–6): PPL.
- chr16:11,547,722–11,798,275, 7 genes, copy number 5–7: LITAF, SNN, TXNDC11, AC007613.1, ZC3H7A, Metazoa_SRP, AC010654.1.
- chr20:35,626,031–35,753,719, 9 genes, copy number 7: CPNE1, AL109827.1, RN7SKP271, RNU6-759P, RBM12, NFS1, ROMO1, RBM39, RPF2P1.
- chr20:57,895,394–59,364,773, 42 genes, copy number 6–7: AL162291.1, AL354984.1, LINC01742, AL354984.2, AL354984.3, C20orf85, ANKRD60, PPP4R1L, RAB22A, VAPB, APCDD1L, APCDD1L-DT, AL050327.1, LINC01711, STX16, STX16-NPEPL1, NPEPL1, AL139349.1, PIEZO1P2, AL132655.3, AL132655.2, MIR296, MIR298, GNAS-AS1, AL132655.1, GNAS, AL132655.7, AL132655.6, AL132655.4, AL132655.5, AL121917.1, AL121917.2, NELFCD, CTSZ, TUBB1, ATP5F1E, PRELID3B, MRPS16P2, ZNF831, EDN3, AL035250.1, AL035250.2.
- chr20:62,841,005–63,472,677, 31 genes, copy number 5 (within-gene range 3–5): TCFL5, DPH3P1, ARF4P2, DIDO1, AL117379.1, GID8, SLC17A9, BHLHE23, LINC01749, LINC00029, LINC01056, HAR1B, AL096828.4, HAR1A, AL096828.2, AL096828.1, MIR124-3, YTHDF1, AL096828.3, BIRC7, MIR3196, NKAIN4, FLJ16779, ARFGAP1, MIR4326, COL20A1, RNU6-994P, CHRNA4, AL121827.1, KCNQ2, AL353658.1.

Autosomal genes at a single copy (total copy number 1): 18,955. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
